CPTAC case C3N-01818 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2573f4bb-998a-4424-b241-3ada0627a92e

Demographics
Sex at birth: male; Race: asian; Year of birth: 1956; Vital status: Dead; Days to death: 270 days; Year of death: 2018; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 60.7 years (22,156 days); Year of diagnosis: 2017; Days to last known disease status: 270 days; Days to last follow up: 221 days.
   Pathology details: Greatest tumor dimension: 6 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 221.

Other clinical attributes
- Weight: 65 kg; Height: 170 cm; BMI: 22.49.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 80; Cigarettes per day: 40; Tobacco smoking onset year: 1976; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 46.

Biospecimens (10 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01818-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 300 mg.
- Sample C3N-01818-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 200 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01818-22: Section location: Left Hemisphere; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-01818-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 500 mg.
- Samples C3N-01818-31, C3N-01818-32, C3N-01818-72, C3N-01818-73, C3N-01818-74, C3N-01818-75 (6 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01818-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -1 day; Method of sample procurement: Blood Draw.
